Somatic mutation profile of tumor specimen TCGA-85-A511-01A (aliquot TCGA-85-A511-01A-21D-A25L-08) from TCGA case TCGA-85-A511, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 62.3 years (22,759 days).
Specimen TCGA-85-A511-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f04a871-71f8-4a55-a097-dddc51c1c26c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-A511-10A (Blood Derived Normal), aliquot TCGA-85-A511-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6a4edf1-22b5-48ad-89a6-06141518d0a0

The open-access MAF lists 207 somatic variants for this specimen: 145 protein-altering or splice-affecting, 52 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 52, Nonsense Mutation 9, Splice Site 4, RNA 3, Frame Shift Del 3, Intron 2, 3'Flank 2, Nonstop Mutation 1, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>T p.C238F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCF2 | c.1558G>T p.G520W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55186049; called by muse, mutect2, varscan2
- ACSS3 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99698332; called by muse, mutect2
- AFF2 | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367644155; called by muse, mutect2
- AK5 | c.935G>T p.S312I (on ENST00000354567 / NM_174858.3; = p.S286I on NM_012093.4) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV100642382; called by muse, mutect2
- AL121899.2 | c.1280A>G p.K427R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101198385; called by muse, mutect2, varscan2
- AMTN | c.565G>A p.G189S | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.207); catalogued as COSV100219664; called by muse, mutect2, varscan2
- ANGPTL5 | c.1019T>C p.L340P | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV100527648; called by muse, mutect2, varscan2
- ASS1 | c.752T>C p.F251S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100752511; called by muse, mutect2, varscan2
- ATP10B | c.1001-1G>C p.X334_splice | Splice Site (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100469093; called by muse, mutect2, varscan2
- ATP8A2 | c.2743C>A p.L915M | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99680179; called by muse, mutect2, varscan2
- ATP8B4 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV52717266; called by muse, mutect2
- CACNA2D3 | c.1479G>C p.K493N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.158); catalogued as COSV99870587; called by muse, mutect2
- CAMKK1 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99339968; called by muse, mutect2, varscan2
- CAPNS1 | c.307A>T p.R103* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as COSV99874460; called by muse, mutect2, varscan2
- CAPRIN2 | c.2326C>T p.H776Y | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51836316; called by muse, mutect2
- CCDC158 | c.1831-2A>C p.X611_splice | Splice Site (SNP) | VAF 27/92 reads (29%) | catalogued as COSV101187158; called by muse, mutect2, varscan2
- CCDC9B | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV101233470; called by muse, mutect2
- CD163 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV100775689; called by muse, mutect2, varscan2
- CDC14A | c.1785A>T p.*595Yext*41 | Nonstop Mutation (SNP) | VAF 33/114 reads (29%) | catalogued as COSV100324466; called by muse, mutect2, varscan2
- CDH10 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100049917, COSV100050168; called by muse, mutect2, varscan2
- CDH10 | c.1362G>T p.W454C | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100049742; called by muse, mutect2, varscan2
- CDH10 | c.1361G>T p.W454L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.666); catalogued as COSV100049745, COSV52582068; called by muse, mutect2, varscan2
- CDH6 | c.1084G>T p.G362W | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99418136; called by muse, mutect2, varscan2
- CFAP206 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV99739169; called by muse, mutect2, varscan2
- COL24A1 | c.2083G>T p.A695S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100992916; called by muse, mutect2, varscan2
- COPE | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99447213; called by muse, mutect2, varscan2
- CX3CL1 | c.1147A>G p.I383V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99136257; called by muse, mutect2, varscan2
- DAAM2 | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.092); catalogued as COSV99224696; called by muse, mutect2, varscan2
- DACT1 | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100241601; called by muse, mutect2, varscan2
- DCAF5 | c.2501A>G p.N834S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1287535880, COSV100432232; called by muse, mutect2, varscan2
- DCBLD2 | c.248C>A p.T83N | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100471480; called by muse, mutect2, varscan2
- DCTN2 | c.292A>G p.T98A (on ENST00000548249 / NM_001261413.2; = p.T103A on NM_006400.4) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63073019; called by muse, mutect2
- DHX57 | c.3194A>T p.D1065V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99769097; called by muse, mutect2, varscan2
- ECT2L | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100871769; called by muse, mutect2, varscan2
- EGF | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.062); catalogued as COSV99490505; called by muse, mutect2, varscan2
- EPYC | c.398A>T p.H133L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99664499; called by muse, mutect2, varscan2
- EVPL | c.3320A>G p.K1107R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs1226337764, COSV100044005; called by muse, mutect2, varscan2
- FAM193A | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100218598; called by muse, mutect2, varscan2
- GABRA4 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs745544149, COSV99973536; called by muse, mutect2, varscan2
- GPR85 | c.764C>A p.T255N | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99775066; called by muse, mutect2, varscan2
- H3C2 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.422); catalogued as rs746725429, COSV52518771; called by muse, mutect2, varscan2
- HEY1 | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100559160; called by muse, mutect2, varscan2
- HOXB3 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100290552; called by muse, mutect2, varscan2
- HSF5 | c.1304T>A p.V435E | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100089839; called by muse, mutect2, varscan2
- IGKV2-30 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs982169289; called by muse, mutect2, varscan2
- IGSF1 | c.379+2T>A p.X127_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100811837; called by muse, mutect2, varscan2
- IL7R | c.1266A>T p.Q422H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV100285932; called by muse, mutect2, varscan2
- IQCN | c.1753C>G p.Q585E | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV101148371; called by muse, mutect2
- KANK4 | c.1873C>A p.P625T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV100587052; called by muse, mutect2, varscan2
- KIF16B | c.2434G>T p.D812Y | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV100733811; called by muse, mutect2, varscan2
- KLHL26 | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99963010; called by muse, mutect2, varscan2
- KNTC1 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100337955; called by muse, mutect2, varscan2
- KRTAP13-1 | c.383G>T p.R128I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100819844, COSV62663368; called by muse, mutect2, varscan2
- LAMA1 | c.1627C>G p.Q543E | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV101055114; called by muse, mutect2, varscan2
- LAMB2 | c.3886G>C p.A1296P | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.69); catalogued as COSV100025853; called by muse, mutect2
- LRP1B | c.10568C>A p.A3523D | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as rs761384397, COSV101252971; called by muse, mutect2, varscan2
- LRP2 | c.1776G>T p.K592N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.567); catalogued as COSV99786659; called by muse, mutect2
- LTF | c.1543G>T p.G515W | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99206889; called by muse, mutect2
- MACF1 | c.14547T>A p.N4849K (on ENST00000372915; = p.N2782K on NM_012090.5) | Missense Mutation (SNP) | VAF 48/191 reads (25%) | catalogued as COSV99241421; called by muse, mutect2, varscan2
- MAGEA12 | c.719C>A p.A240E | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100756809, COSV63295598; called by muse, mutect2, varscan2
- MMP19 | c.827C>A p.P276H | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100490976; called by muse, mutect2, varscan2
- MRC1 | c.2791G>C p.A931P | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.634); catalogued as COSV99519306; called by muse, mutect2
- MUC16 | c.31726G>T p.G10576W | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.797); catalogued as rs1555838421, COSV101198277; called by muse, mutect2, varscan2
- MUC16 | c.16074C>G p.I5358M | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV101198278, COSV67460923; called by muse, mutect2
- MUC16 | c.14981C>G p.S4994* | Nonsense Mutation (SNP) | VAF 9/110 reads (8%) | catalogued as COSV101198279; called by muse, mutect2
- MUC17 | c.4228A>T p.S1410C | Missense Mutation (SNP) | VAF 62/462 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV100071690; called by muse, mutect2, varscan2
- MYCBP2 | c.8298G>C p.M2766I (on ENST00000357337; = p.M2804I on NM_015057.5) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100629279; called by muse, mutect2, varscan2
- MYF6 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.143); catalogued as rs535543850, COSV57351541; called by muse, mutect2, varscan2
- MYO3B | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.405); catalogued as COSV100509226, COSV58695286; called by muse, mutect2, varscan2
- MYO5C | c.3365+2T>A p.X1122_splice | Splice Site (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99954123; called by muse, mutect2
- NAALAD2 | c.935C>A p.A312D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100428061; called by muse, mutect2, varscan2
- NBEA | c.1426C>A p.L476I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV100077025; called by muse, mutect2, varscan2
- NEK2 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1352594832, COSV100878519; called by muse, mutect2, varscan2
- NEMP1 | c.1135C>T p.R379* (on ENST00000300128 / NM_001130963.2; = p.R306* on NM_015257.3) | Nonsense Mutation (SNP) | VAF 19/112 reads (17%) | catalogued as COSV55662788, COSV55663187; called by muse, mutect2, varscan2
- NEO1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV99981311; called by mutect2, varscan2
- NOMO2 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.875); catalogued as rs780641252, COSV100395525, COSV100395873; called by mutect2, varscan2
- NOTCH3 | c.1151C>G p.T384R | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV99655959, COSV99657834; called by muse, mutect2
- NSD2 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.401); catalogued as COSV100372852; called by muse, mutect2
- OCA2 | c.991G>C p.V331L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV100666992; called by muse, mutect2
- OGDHL | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201783448, COSV65103304; called by muse, mutect2, varscan2
- OPN5 | c.729C>A p.S243R | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV99789724; called by muse, mutect2, varscan2
- OPRPN | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV101271076, COSV68192548; called by muse, mutect2, varscan2
- OR13C2 | c.64A>G p.R22G | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101604856; called by muse, mutect2, varscan2
- OR2L13 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 56/225 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100813679; called by muse, mutect2, varscan2
- OR2T34 | c.165C>A p.H55Q | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.067); catalogued as COSV100170252; called by muse, mutect2
- OR52N4 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100421573; called by muse, mutect2, varscan2
- OR5K3 | c.812C>G p.P271R | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.579); catalogued as COSV67350453; called by muse, mutect2
- OR6N1 | c.380G>C p.C127S | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100625080, COSV58648903; called by muse, mutect2, varscan2
- PCDH17 | c.2806G>T p.E936* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV64974532; called by muse, mutect2
- PCDHA9 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100969067, COSV65323981; called by muse, mutect2, varscan2
- PCSK5 | c.468G>C p.W156C | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949522; called by muse, mutect2, varscan2
- PLEKHG4 | c.1985A>G p.Q662R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100430673; called by mutect2, varscan2
- POGZ | c.3577G>C p.E1193Q | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99304805; called by muse, mutect2
- POLR1B | c.2365G>A p.D789N | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99637153; called by muse, mutect2
- POP1 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100855642; called by muse, mutect2, varscan2
- PPP6R3 | c.1243C>G p.Q415E (on ENST00000393800 / NM_001352375.2; = p.Q364E on NM_018312.5) | Missense Mutation (SNP) | VAF 68/301 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as COSV99675650; called by muse, mutect2, varscan2
- PRTG | c.631G>C p.A211P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV101221280, COSV66838704; called by muse, mutect2
- PTPRC | c.3520C>A p.Q1174K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as COSV100722147; called by muse, mutect2, varscan2
- R3HDM2 | c.2641A>T p.T881S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100234488; called by muse, mutect2, varscan2
- RAB11FIP2 | c.1108A>G p.R370G | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs1272209575, COSV100842995; called by muse, mutect2, varscan2
- RASSF4 | c.622A>T p.N208Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.328); catalogued as COSV100436769; called by muse, mutect2, varscan2
- ROBO1 | c.2099A>T p.Q700L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); catalogued as COSV101458320; called by muse, mutect2, varscan2
- ROBO3 | c.1669G>T p.G557W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101184921, COSV101185212; called by muse, mutect2, varscan2
- RP1L1 | c.215T>G p.V72G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100261600; called by muse, mutect2, varscan2
- RPF2 | c.91A>T p.K31* | Nonsense Mutation (SNP) | VAF 24/131 reads (18%) | catalogued as COSV100923238; called by muse, mutect2, varscan2
- SEC16B | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as rs1470571187, COSV100381266; called by muse, mutect2, varscan2
- SEMA3D | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99405891; called by muse, mutect2
- SFN | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | catalogued as COSV100212775, COSV59433995; called by muse, mutect2
- SLC39A12 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV101069853; called by muse, mutect2, varscan2
- SLC8A3 | c.1534G>C p.V512L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs767563263, COSV100775906; called by muse, mutect2, varscan2
- SMC5 | c.2158C>G p.L720V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV100746967; called by muse, mutect2
- SNAI1 | c.148C>T p.L50F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV99723821; called by muse, mutect2, varscan2
- TFAP2D | c.196T>C p.Y66H | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.969); catalogued as COSV99145688; called by muse, mutect2, varscan2
- TG | c.7064G>T p.G2355V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99599209; called by muse, mutect2, varscan2
- TGFBR2 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99846568; called by muse, mutect2, varscan2
- THEMIS | c.777C>G p.Y259* | Nonsense Mutation (SNP) | VAF 34/165 reads (21%) | catalogued as COSV100965257; called by muse, mutect2, varscan2
- TLR7 | c.991G>T p.G331W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1294110815, COSV101027730; called by muse, mutect2, varscan2
- TLR7 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs1328692782, COSV101027731; called by muse, mutect2, varscan2
- TRIM24 | c.1909A>T p.N637Y (on ENST00000343526 / NM_015905.3; = p.N603Y on NM_003852.4) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100630674; called by muse, mutect2, varscan2
- TRIP11 | c.2508G>T p.Q836H | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs1185580561, COSV50921526; called by muse, mutect2, varscan2
- UGT2A1 | c.178T>C p.F60L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.197); catalogued as COSV99683864; called by muse, mutect2, varscan2
- UGT2B17 | c.1271G>C p.R424T | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100497167; called by muse, mutect2
- UNC79 | c.4825G>T p.D1609Y (on ENST00000393151 / NM_001346218.2; = p.D1432Y on NM_020818.5) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99825979; called by muse, mutect2, varscan2
- USP29 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54241971, COSV99571746; called by muse, mutect2, varscan2
- VNN1 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV100907690; called by muse, mutect2, varscan2
- XIRP2 | c.192C>A p.Y64* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99738797; called by muse, mutect2, varscan2
- XRCC4 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs778723397, COSV99982040; called by muse, mutect2, varscan2
- ZBTB41 | c.1954A>G p.S652G | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100962844; called by muse, mutect2
- ZIM2 | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1429599638, COSV99687447; called by muse, mutect2
- ZNF292 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.603); catalogued as COSV100369809; called by muse, mutect2, varscan2
- ZNF292 | c.2183G>T p.R728M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100369811; called by muse, mutect2, varscan2
- ZNF417 | c.32A>T p.Q11L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100364094; called by muse, mutect2
- ZNF804A | c.2506G>T p.V836L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs774222712, COSV100166521, COSV56451524; called by muse, mutect2, varscan2
- ARHGEF15 | c.2025G>T p.Q675H | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- CBLB | c.454C>G p.H152D | Missense Mutation (SNP) | VAF 5/109 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSNK2A1 | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GEN1 | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- H2BU1 | c.182dup p.I62Hfs*8 | Frame Shift Ins (INS) | VAF 18/154 reads (12%) | called by mutect2, pindel, varscan2
- OR10A4 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.038); called by muse, mutect2
- OR4C12 | c.900del p.W300* | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | called by mutect2, pindel, varscan2
- PDCD2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- RET | c.2322del p.E775Sfs*5 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- RIMS2 | c.4148G>C p.R1383P (on ENST00000666250 / NM_001348490.2; = p.R954P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TTLL9 | c.205del p.D69Tfs*39 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- AASS | c.273A>T p.G91= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100741671; called by muse, mutect2
- AHSG | c.996A>G p.E332= | Silent (SNP) | VAF 63/144 reads (44%) | catalogued as COSV99889862; called by muse, mutect2, varscan2
- ALPK1 | c.2367A>G p.G789= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99453118; called by muse, mutect2, varscan2
- AP5S1 | c.264G>T p.V88= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99853206; called by muse, mutect2, varscan2
- ASAH2 | c.270C>A p.T90= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as rs779014422, COSV100269813; called by muse, mutect2, varscan2
- ATP10A | c.2211G>A p.L737= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV100790900; called by muse, mutect2
- ATP8A2 | c.987G>A p.L329= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99680177; called by muse, mutect2, varscan2
- BMP10 | c.996C>T p.F332= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV99770284; called by muse, mutect2, varscan2
- CCDC40 | c.981G>T p.L327= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99481332; called by muse, mutect2, varscan2
- CDH10 | c.2190C>T p.Y730= | Silent (SNP) | VAF 29/185 reads (16%) | catalogued as rs542487965, COSV52574109; called by muse, mutect2, varscan2
- CFAP61 | c.720G>A p.G240= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV99843417; called by muse, mutect2, varscan2
- COX4I1 | c.123G>T p.R41= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99495345; called by muse, mutect2, varscan2
- CYP2R1 | c.1437A>C p.P479= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV100584851; called by muse, mutect2, varscan2
- EP400 | c.1344C>A p.A448= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100200477; called by muse, mutect2
- FBN3 | c.6837T>C p.C2279= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99559921; called by muse, mutect2, varscan2
- FBXO15 | c.1299A>G p.E433= | Silent (SNP) | VAF 24/148 reads (16%) | catalogued as COSV99503062; called by muse, mutect2, varscan2
- FZD7 | c.588G>T p.G196= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1241599461, COSV99636851; called by muse, mutect2, varscan2
- GRIA2 | c.1416G>T p.G472= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99643134; called by muse, mutect2, varscan2
- HDAC9 | c.3051G>T p.V1017= (on ENST00000441542 / NM_178425.3; = p.V1014= on NM_178423.3) | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV101286351; called by muse, mutect2
- HIVEP2 | c.6597C>T p.S2199= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV99171485; called by muse, mutect2
- IQCJ-SCHIP1 | c.219C>A p.S73= | Silent (SNP) | VAF 52/121 reads (43%) | catalogued as COSV101188013; called by muse, mutect2, varscan2
- ITGB1BP2 | c.87G>T p.G29= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- LEPR | c.3183G>A p.L1061= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as COSV100847885; called by muse, mutect2, varscan2
- MAP3K13 | c.2238C>G p.P746= | Silent (SNP) | VAF 129/256 reads (50%) | catalogued as rs1560133374, COSV53996248, COSV99406500; called by muse, mutect2, varscan2
- MARF1 | c.1173C>A p.I391= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- METAP2 | c.90G>T p.T30= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99704673; called by muse, mutect2, varscan2
- MYH6 | c.5458C>A p.R1820= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as COSV100197934; called by muse, mutect2
- NAF1 | c.147G>T p.G49= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99918921; called by mutect2, varscan2
- NAPEPLD | c.846A>T p.A282= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100439701; called by muse, mutect2, varscan2
- OGDH | c.2196C>T p.F732= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs749269578, COSV56050301; called by muse, mutect2, varscan2
- OGDHL | c.729C>A p.A243= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100934207; called by muse, mutect2, varscan2
- OR10W1 | c.282C>T p.F94= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1176526367, COSV101223610; called by muse, mutect2
- OR2H1 | c.543T>A p.S181= | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as COSV101009781; called by muse, mutect2, varscan2
- OR2T6 | c.717C>A p.A239= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100861487, COSV63215937; called by muse, mutect2, varscan2
- OR2W3 | c.873C>G p.T291= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100831597; called by muse, mutect2, varscan2
- OR51F1 | c.303C>T p.I101= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100598662; called by muse, mutect2, varscan2
- OR8H3 | c.936G>A p.R312= | Silent (SNP) | VAF 8/117 reads (7%) | catalogued as rs1259254385, COSV100538754; called by muse, mutect2
- PAH | c.336T>C p.D112= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100187655; called by muse, mutect2, varscan2
- PCDHA4 | c.1314G>T p.T438= | Silent (SNP) | VAF 39/135 reads (29%) | catalogued as COSV100793173; called by muse, mutect2, varscan2
- PKHD1L1 | c.4938G>T p.T1646= | Silent (SNP) | VAF 50/258 reads (19%) | catalogued as rs571376584, COSV101005455; called by muse, mutect2, varscan2
- PTPN14 | c.1608G>T p.T536= | Silent (SNP) | VAF 27/146 reads (18%) | catalogued as COSV65287112; called by muse, mutect2, varscan2
- PTPRC | c.2157C>A p.P719= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as COSV61419250; called by muse, mutect2, varscan2
- RERGL | c.261T>C p.S87= | Silent (SNP) | VAF 30/185 reads (16%) | catalogued as COSV99967767; called by muse, mutect2, varscan2
- RYR2 | c.8982A>T p.G2994= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100768164; called by muse, mutect2, varscan2
- SAAL1 | c.15C>T p.P5= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100253744, COSV55515854; called by muse, mutect2, varscan2
- SDK1 | c.5796C>T p.T1932= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV101268803; called by muse, mutect2, varscan2
- SPAG17 | c.1335G>T p.L445= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100308023; called by muse, mutect2, varscan2
- SPATA31A3 | c.3777C>A p.G1259= | Silent (SNP) | VAF 10/32 reads (31%) | called by mutect2, varscan2
- SYNE1 | c.16152G>A p.K5384= (on ENST00000367255 / NM_182961.4; = p.K5313= on NM_033071.3) | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV55002418; called by muse, mutect2, varscan2
- TBC1D24 | c.195C>T p.R65= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99564679; called by muse, mutect2, varscan2
- TMEM131 | c.2646A>G p.V882= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs755637207, COSV99486640; called by muse, mutect2
- ZNF513 | c.1215G>T p.R405= | Silent (SNP) | VAF 32/243 reads (13%) | catalogued as COSV99277285; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 4/28 reads (14%) | catalogued as rs201441562; called by pindel, varscan2
- AP000769.5 | chr11:65499033 G>T | 5'Flank (SNP) | VAF 28/101 reads (28%) | catalogued as rs1301258702; called by muse, mutect2, varscan2
- DELEC1 | n.731G>C | RNA (SNP) | VAF 6/33 reads (18%) | catalogued as COSV64983297, COSV64986093; called by muse, mutect2, varscan2
- EHMT1 | chr9:137838462 G>T | 3'Flank (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1G>A | 3'UTR (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100646260; called by muse, mutect2
- MIR1270 | chr19:20397577 A>G | 3'Flank (SNP) | VAF 19/129 reads (15%) | called by muse, mutect2, varscan2
- SNORD115-8 | n.39A>T | RNA (SNP) | VAF 26/199 reads (13%) | called by muse, mutect2, varscan2
- SV2C | c.581-21223C>T | Intron (SNP) | VAF 42/222 reads (19%) | catalogued as rs373807968; called by muse, mutect2, varscan2
- TRAPPC6A | c.-2G>T | 5'UTR (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99135272; called by muse, mutect2, varscan2
- XIST | n.10025C>G | RNA (SNP) | VAF 6/30 reads (20%) | catalogued as rs767870206; called by muse, mutect2, varscan2
